Somatic mutation profile of tumor specimen 0DOXH1 from CCDI case PBCBTJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 20.3 years (7,425 days).
Specimen 0DOXH1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fafcc79-a19d-4ca6-bec0-c22c32900bea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOXFY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c471c7c-5629-415e-9276-78d7a8af2c94

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 3'Flank 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP3 | c.3370A>G p.K1124E | Missense Mutation (SNP) | VAF 134/857 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV52676873; called by muse, mutect2, varscan2
- RALGAPA2 | c.150C>G p.N50K | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs931417635; called by muse, mutect2, varscan2
- SNRK | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 69/426 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs568652187; called by muse, mutect2, varscan2
- TRPV1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs200558506; called by muse, mutect2, varscan2
- ADGRL3 | c.1638T>A p.D546E (on ENST00000506720 / NM_001322402.2; = p.D478E on NM_015236.6) | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRIQ4 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 68/773 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.057); called by muse, mutect2
- PCDHB8 | c.1183A>G p.K395E | Missense Mutation (SNP) | VAF 46/1350 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- RXFP2 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 65/520 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCB1 | c.459_460del p.K153Nfs*11 (on ENST00000263121; = p.K199Nfs*11 on NM_003073.5) | Frame Shift Del (DEL) | VAF 60/236 reads (25%) | called by mutect2, varscan2
- KCNJ3 | c.984T>C p.F328= | Silent (SNP) | VAF 140/945 reads (15%) | catalogued as rs760085492, COSV54531552, COSV54536267; called by muse, mutect2, varscan2
- PCDHB8 | c.1182G>T p.L394= | Silent (SNP) | VAF 49/1359 reads (4%) | called by muse, mutect2
- SYN1 | c.1893T>A p.R631= | Silent (SNP) | VAF 19/140 reads (14%) | called by muse, mutect2, varscan2
- TCF19 | c.696G>A p.A232= | Silent (SNP) | VAF 48/285 reads (17%) | catalogued as rs1231117209, COSV52563026; called by muse, mutect2, varscan2
- DGKH | c.3443-51A>C | Intron (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- SLC10A7 | chr4:146256446 A>C | 3'Flank (SNP) | VAF 91/486 reads (19%) | called by muse, mutect2, varscan2
- UBXN11 | chr1:26282262 G>A | 3'Flank (SNP) | VAF 21/67 reads (31%) | catalogued as rs757230937; called by muse, mutect2, varscan2
